Gene-level copy-number profile of tumor specimen TCGA-12-0670-01B from TCGA case TCGA-12-0670, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 60.8 years (22,189 days).
Specimen TCGA-12-0670-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.ca05c33d-4e8c-4d30-bec8-257ba0b34386.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-12-0670-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0f7822b9-b604-47d0-83cc-cdab4e5022c3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 8,249; copy number 2: 43,829; copy number 3: 7,520; copy number 4: 45; copy number 5: 33; copy number 6: 8; copy number 7: 3; copy number 8: 54; copy number 9: 2; copy number 11: 5; copy number 12: 15; copy number 19: 4; copy number 23: 24; copy number 25: 2; copy number 26: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-12-0670-01B-01D-0384-01): tumor purity 0.89, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,929,457–22,824,213, 12 genes: ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239.
- chr9:22,747,700–22,768,316, 2 genes: CLIC4P1, AC017067.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 161 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:32,457,835–33,080,996, 23 genes, copy number 23 (within-gene range 2–23): RN7SL122P, AL033529.1, ZBTB8B, ZBTB8A, ZBTB8OS, Y_RNA, RBBP4, SYNC, AC114489.1, KIAA1522, YARS1, S100PBP, FNDC5, HPCA, TMEM54, AL031602.2, RNF19B, AL031602.1, AL355864.1, AL355864.2, AL020995.1, AK2, Metazoa_SRP.
- chr7:54,676,217–55,260,256, 10 genes, copy number 26: AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2.
- chr12:57,249,609–58,244,865, 56 genes, copy number 5–8 (within-gene range 1–8): AC137834.1, R3HDM2, RNU6-879P, AC126614.1, INHBC, INHBE, AC022506.2, GLI1, ARHGAP9, MARS1, MIR6758, DDIT3, AC022506.1, MIR616, MBD6, DCTN2, KIF5A, PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103.
- chr12:59,596,029–59,812,576, 3 genes, copy number 5–9 (within-gene range 1–9): SLC16A7, AC079905.2, AC079905.1.
- chr12:61,600,067–62,279,150, 4 genes, copy number 6–7 (within-gene range 1–23): DUX4L52, AC090629.1, TAFA2, RPL21P104.
- chr12:62,021,570–62,022,174, 1 gene, copy number 23: RPS3P6.
- chr12:62,234,390–62,235,515, 1 gene, copy number 6: KLF17P1.
- chr12:62,260,359–62,260,454, 1 gene, copy number 6: MIR6125.
- chr12:63,003,553–63,006,902, 2 genes, copy number 5: LDHAL6CP, AC078814.1.
- chr12:63,822,021–64,162,217, 7 genes, copy number 11–25 (within-gene range 1–25): PABPC1P4, SRGAP1, RPL36AP41, AC079866.2, AC079866.1, AC020611.1, AC020611.2.
- chr12:65,169,583–65,663,299, 10 genes, copy number 5: LEMD3, AC026124.2, MSRB3, AC026124.1, KRT18P60, AC025419.1, AC090023.1, LINC02454, AC090023.2, PCNPP3.
- chr12:66,347,431–67,069,162, 1 gene, copy number 5 (within-gene range 1–5): GRIP1.
- chr12:66,950,754–67,266,966, 4 genes, copy number 5–26: AC073530.1, AC073530.2, RAB11AP2, GGTA2P.
- chr12:67,571,197–68,234,686, 10 genes, copy number 5–6 (within-gene range 1–6): LINC02442, DYRK2, AC078777.1, LINC02421, AC022513.1, LINC01479, AC005294.1, IFNG-AS1, RPL39P28, HNRNPA1P70.
- chr12:68,575,858–68,850,686, 15 genes, copy number 12: Metazoa_SRP, RAP1B, RPL10P12, SNORA70G, ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2.
- chr12:69,212,108–69,285,485, 4 genes, copy number 19: AC127894.1, CPSF6, MIR1279, C1GALT1P1.
- chr12:70,906,917–71,594,404, 9 genes, copy number 5: Y_RNA, AC123905.1, AC025575.1, AC025575.2, TSPAN8, LGR5, AC090116.1, AC078860.3, AC078860.2.

Autosomal genes at a single copy (total copy number 1): 5,863. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
